Somatic mutation profile of tumor specimen MMRF_1284_1_BM_CD138pos (aliquot MMRF_1284_1_BM_CD138pos_T1_KAS5U_L01369) from MMRF case MMRF_1284, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 59.8 years (21,830 days).
Specimen MMRF_1284_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 62731de5-6cc8-4c43-a68e-a2730730cec5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1284_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1284_1_PB_Whole_C2_KAS5U_L01381; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/56dc9756-00dd-4fc2-9092-d0c97c8ee153

The open-access MAF lists 66 somatic variants for this specimen: 21 protein-altering or splice-affecting, 13 silent, 32 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 16, Silent 13, 3'UTR 13, Intron 11, 5'UTR 4, Nonsense Mutation 3, 3'Flank 2, RNA 2, Nonstop Mutation 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.182A>G p.Q61R | Missense Mutation (SNP) | VAF 23/44 reads (52%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen benign (0.122); catalogued as rs121913240, COSV55498739, COSV55504296, COSV55508574; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCC12 | c.862C>T p.R288* | Nonsense Mutation (SNP) | VAF 28/70 reads (40%) | catalogued as rs780376202; called by muse, mutect2, varscan2
- ASXL3 | c.6742C>T p.R2248* | Nonsense Mutation (SNP) | VAF 22/41 reads (54%) | catalogued as rs1268450717, COSV52459252; called by muse, mutect2, varscan2
- CCN3 | c.834C>A p.F278L | Missense Mutation (SNP) | VAF 33/93 reads (35%) | SIFT tolerated (0.55); PolyPhen benign (0.136); catalogued as COSV52384949; called by muse, mutect2, varscan2
- CCN4 | c.182G>A p.R61H | Missense Mutation (SNP) | VAF 32/41 reads (78%) | SIFT tolerated (0.16); PolyPhen benign (0.138); catalogued as COSV51531200; called by muse, mutect2, varscan2
- CDKN1B | c.596A>C p.*199Sext*60 | Nonstop Mutation (SNP) | VAF 53/112 reads (47%) | catalogued as COSV57430013, COSV57431103; called by muse, mutect2, varscan2
- DNAAF2 | c.1015C>T p.R339W | Missense Mutation (SNP) | VAF 24/47 reads (51%) | SIFT deleterious (0.02); PolyPhen benign (0.017); catalogued as rs770686606; called by muse, mutect2, varscan2
- EMB | c.188C>T p.S63L | Missense Mutation (SNP) | VAF 112/381 reads (29%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.991); catalogued as rs893442296, COSV100296548; called by muse, mutect2, varscan2
- IGHV1-2 | c.47-1G>A p.X16_splice | Splice Site (SNP) | VAF 24/37 reads (65%) | catalogued as rs527238172; called by muse, mutect2, varscan2
- IGHV2-70 | c.96A>C p.K32N | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs368957766; called by muse, varscan2
- JAKMIP1 | c.2230C>T p.R744W | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT tolerated (0.18); PolyPhen benign (0.436); catalogued as rs377012431; called by muse, mutect2, varscan2
- RAD54L2 | c.1400G>A p.R467H | Missense Mutation (SNP) | VAF 5/83 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1559646800, COSV56578104; called by muse, mutect2
- APOB | c.2318C>A p.A773D | Missense Mutation (SNP) | VAF 44/106 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ASB7 | c.806A>G p.Q269R | Missense Mutation (SNP) | VAF 20/42 reads (48%) | SIFT tolerated, low confidence (0.77); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- BAZ1B | c.3679C>T p.Q1227* | Nonsense Mutation (SNP) | VAF 3/37 reads (8%) | called by muse, mutect2
- CLCN1 | c.251C>A p.S84Y | Missense Mutation (SNP) | VAF 26/64 reads (41%) | SIFT tolerated (0.11); PolyPhen benign (0.127); called by muse, mutect2, varscan2
- DNAH12 | c.1087A>G p.N363D | Missense Mutation (SNP) | VAF 6/146 reads (4%) | SIFT tolerated (0.65); PolyPhen benign (0.034); called by muse, mutect2
- MYO15A | c.2185C>T p.P729S | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.327); called by muse, mutect2, varscan2
- NAA15 | c.1318G>A p.A440T | Missense Mutation (SNP) | VAF 29/78 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- PCSK6 | c.1949T>A p.L650Q | Missense Mutation (SNP) | VAF 26/69 reads (38%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.929); called by muse, mutect2, varscan2
- REST | c.3080G>A p.S1027N | Missense Mutation (SNP) | VAF 44/99 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ACSS2 | c.240T>C p.L80= | Silent (SNP) | VAF 71/82 reads (87%) | called by muse, mutect2, varscan2
- CEP83 | c.621C>T p.S207= | Silent (SNP) | VAF 41/96 reads (43%) | called by muse, mutect2, varscan2
- CER1 | c.336C>T p.L112= | Silent (SNP) | VAF 40/132 reads (30%) | catalogued as COSV101097707; called by muse, mutect2, varscan2
- CLSTN2 | c.2685G>A p.G895= | Silent (SNP) | VAF 13/54 reads (24%) | catalogued as rs772978569, COSV71721228; called by muse, varscan2
- CTCFL | c.1980G>A p.T660= | Silent (SNP) | VAF 31/72 reads (43%) | catalogued as rs755523255; called by muse, mutect2, varscan2
- GCGR | c.1107G>A p.T369= | Silent (SNP) | VAF 31/74 reads (42%) | catalogued as rs528390403; called by muse, mutect2, varscan2
- GORASP1 | c.843C>T p.D281= | Silent (SNP) | VAF 13/55 reads (24%) | catalogued as rs1302743319; called by muse, mutect2, varscan2
- IGHV1-2 | c.39A>C p.A13= | Silent (SNP) | VAF 28/47 reads (60%) | called by muse, mutect2, varscan2
- LAMA3 | c.5175C>T p.N1725= (on ENST00000313654 / NM_198129.4; = p.N116= on NM_000227.6) | Silent (SNP) | VAF 24/64 reads (38%) | catalogued as rs746646266; called by muse, mutect2, varscan2
- PRPF3 | c.1737C>T p.V579= | Silent (SNP) | VAF 25/54 reads (46%) | called by muse, mutect2, varscan2
- TLE2 | c.1623C>T p.A541= | Silent (SNP) | VAF 57/99 reads (58%) | catalogued as rs112201116; called by muse, mutect2, varscan2
- YEATS2 | c.2559C>T p.I853= | Silent (SNP) | VAF 25/81 reads (31%) | called by muse, mutect2, varscan2
- ZNF697 | c.1311C>T p.Y437= | Silent (SNP) | VAF 19/35 reads (54%) | catalogued as rs371820983; called by muse, mutect2, varscan2
- ABI3BP | c.1063+39A>G | Intron (SNP) | VAF 24/74 reads (32%) | called by muse, mutect2, varscan2
- AC108729.3 | chr3:155375653 G>C | 3'Flank (SNP) | VAF 86/278 reads (31%) | called by muse, mutect2, varscan2
- ACSS3 | c.922-80T>C | Intron (SNP) | VAF 54/118 reads (46%) | called by muse, mutect2, varscan2
- AGO3 | c.658+9696A>C | Intron (SNP) | VAF 12/36 reads (33%) | called by muse, mutect2, varscan2
- AL359195.2 | n.3204T>C | RNA (SNP) | VAF 65/156 reads (42%) | called by muse, mutect2, varscan2
- ATAD2 | c.*824T>A | 3'UTR (SNP) | VAF 43/101 reads (43%) | called by muse, mutect2, varscan2
- DCUN1D4 | c.*3032G>A | 3'UTR (SNP) | VAF 22/49 reads (45%) | called by muse, mutect2, varscan2
- EEF1A1 | c.-38G>A | 5'UTR (SNP) | VAF 17/28 reads (61%) | called by muse, mutect2, varscan2
- ERMN | c.*271C>T | 3'UTR (SNP) | VAF 30/68 reads (44%) | called by muse, mutect2, varscan2
- ESR1 | c.*268C>T | 3'UTR (SNP) | VAF 27/68 reads (40%) | catalogued as rs991255100; called by muse, mutect2, varscan2
- F2RL2 | c.*1623A>C | 3'UTR (SNP) | VAF 25/114 reads (22%) | called by muse, mutect2, varscan2
- GABRB3 | c.241-7615C>A | Intron (SNP) | VAF 4/20 reads (20%) | called by muse, mutect2
- HBZ | c.-181G>A | 5'UTR (SNP) | VAF 14/17 reads (82%) | called by muse, mutect2
- KAT7 | c.15+225G>T | Intron (SNP) | VAF 23/52 reads (44%) | called by mutect2, varscan2
- KRTAP9-9 | c.*263A>C | 3'UTR (SNP) | VAF 33/87 reads (38%) | called by muse, mutect2, varscan2
- LUC7L3 | c.*34-325A>C | Intron (SNP) | VAF 13/42 reads (31%) | called by muse, mutect2, varscan2
- MYO15A | c.9387-257A>C | Intron (SNP) | VAF 6/9 reads (67%) | catalogued as rs887383111; called by muse, mutect2, varscan2
- NALCN | c.*697A>C | 3'UTR (SNP) | VAF 21/50 reads (42%) | called by muse, mutect2, varscan2
- NECTIN1 | c.79+14619G>T | Intron (SNP) | VAF 16/68 reads (24%) | called by muse, mutect2, varscan2
- OR6W1P | n.912G>A | RNA (SNP) | VAF 33/70 reads (47%) | called by muse, mutect2, varscan2
- OSTM1 | c.*54A>G | 3'UTR (SNP) | VAF 55/120 reads (46%) | called by muse, mutect2, varscan2
- PCDH19 | c.*1274G>A | 3'UTR (SNP) | VAF 16/17 reads (94%) | called by muse, mutect2, varscan2
- PDE7A | c.*176G>C | 3'UTR (SNP) | VAF 13/47 reads (28%) | called by muse, mutect2, varscan2
- PLA2G2F | c.-9A>G | 5'UTR (SNP) | VAF 32/67 reads (48%) | called by muse, mutect2, varscan2
- RAB40B | c.*93T>C | 3'UTR (SNP) | VAF 37/86 reads (43%) | called by muse, mutect2, varscan2
- RPL32 | c.-182A>G | 5'UTR (SNP) | VAF 49/177 reads (28%) | catalogued as rs1417767315; called by muse, mutect2, varscan2
- TBC1D26 | c.667-63C>T | Intron (SNP) | VAF 7/19 reads (37%) | called by muse, mutect2, varscan2
- TENM4 | c.*2949G>A | 3'UTR (SNP) | VAF 30/122 reads (25%) | called by muse, mutect2, varscan2
- TRIM22 | c.*640del | 3'UTR (DEL) | VAF 21/125 reads (17%) | called by mutect2, pindel, varscan2
- TXNIP | c.251-22A>G | Intron (SNP) | VAF 84/219 reads (38%) | called by muse, mutect2, varscan2
- VAV3 | c.1706-51C>T | Intron (SNP) | VAF 62/172 reads (36%) | called by muse, mutect2, varscan2
- WDR89 | chr14:63597902 C>A | 3'Flank (SNP) | VAF 44/97 reads (45%) | called by muse, mutect2, varscan2
